Somatic mutation profile of tumor specimen BA3280D (aliquot aq-BA3280D) from BEATAML1.0 case 2648, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.2 years (18,707 days).
Specimen BA3280D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38a0514f-5a11-4036-b63b-1ed30367c2c6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3122D (Solid Tissue Normal), aliquot aq-BA3122D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7954be6-b7d2-49ed-8dc4-6af68bf38c04

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 20/170 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAM155A | c.1178T>A p.V393E | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs145827476; called by muse, mutect2, varscan2
- STAG2 | c.2139C>G p.Y713* | Nonsense Mutation (SNP) | VAF 34/41 reads (83%) | catalogued as COSV54366695; called by mutect2, varscan2
- WWC1 | c.1912G>A p.V638M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs747331058; called by muse, mutect2, varscan2
- MED24 | c.363C>T p.C121= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100673214; called by muse, mutect2
